Somatic mutation profile of tumor specimen TCGA-CH-5763-01A (aliquot TCGA-CH-5763-01A-11D-1576-08) from TCGA case TCGA-CH-5763, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.7 years (24,380 days).
Specimen TCGA-CH-5763-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 078a7bc7-a73d-4476-85b0-99c99a5673ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CH-5763-11A (Solid Tissue Normal), aliquot TCGA-CH-5763-11A-01D-1576-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d1470ab-dc79-45d9-963e-ccb9bc310202

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AK7 | c.693G>A p.M231I | Missense Mutation (SNP) | VAF 16/474 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV50875193; called by muse, mutect2
- LRIG3 | c.3053C>T p.S1018F | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.136); catalogued as COSV57866556; called by muse, mutect2
- OR5B17 | c.68T>G p.V23G | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV62160625; called by muse, mutect2
- SNCAIP | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.354); catalogued as rs199933356; called by muse, mutect2
- TRIM6 | c.1319A>G p.E440G | Missense Mutation (SNP) | VAF 16/391 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); catalogued as COSV53477342; called by muse, mutect2
- UBTF | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57187233; called by muse, mutect2
- MED13L | c.1557G>T p.V519= | Silent (SNP) | VAF 8/111 reads (7%) | catalogued as COSV56124122; called by muse, mutect2
- ZER1 | c.1836G>A p.Q612= | Silent (SNP) | VAF 12/202 reads (6%) | catalogued as COSV52566974; called by muse, mutect2
- CCDC140 | n.657G>C | RNA (SNP) | VAF 4/52 reads (8%) | catalogued as COSV54676157; called by muse, mutect2
